Gene-level copy-number profile of tumor specimen REBC-ACEL-TTP1-A from REBC case REBC-ACEL, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: female; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-ACEL-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0dbd0443-0727-4da7-af6a-bfd7778c143e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-ACEL-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/015c01c1-4cf9-4d2d-894e-69fd4a7024c2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 341; copy number 2: 58,008; copy number 3: 36.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:20,740,266–20,787,323, 1 gene: HP1BP3.
- chr5:131,245,493–131,398,447, 2 genes: CDC42SE2, AC004777.1.
- chr10:23,343,957–23,345,181, 1 gene (within-gene range 0–2): AL606469.1.
- chr17:439,978–445,939, 1 gene: RFLNB.
- chr18:46,917,492–47,102,243, 8 genes (within-gene range 0–2): KATNAL2, ELOA3D, ELOA3C, ELOA3B, ELOA3, ELOA2, AC012254.5, AC012254.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 341. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
